MMRF case MMRF_1602 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1c58074b-2bfd-4177-8fb4-22561402bbcc

Demographics
Sex at birth: male; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.7 years (24,375 days); ISS stage: I; Days to last known disease status: 1,261 days (3.5 years); Days to last follow up: 1,261 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 83 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 116 days; Days to treatment end: 116 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 116 days; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 265 days; Days to treatment end: 704 days (1.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,041 days (2.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1: M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 124 mg/dL; Immunoglobulin G 5.02 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.22 µg/mL; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 6.16 mmol/L; C-Reactive Protein 0.274 mg/dL.
- Day 78: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 3.75 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 1.69 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.45 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 3.58 mmol/L.
- Day 162 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 3.86 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.84 µg/mL; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.18 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 6.22 mmol/L.
- Day 288 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 5.09 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.35 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.
- Day 459 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 6.61 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 5.89 mmol/L.
- Day 484 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 6.21 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.58 µg/mL; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.17 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 6.55 mmol/L.
- Day 643 (ECOG 1): Hemoglobin 8.68 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 74 ×10⁹/L.
- Day 704 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 6.78 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.94 mmol/L.
- Day 869 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 6.85 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.94 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.62 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 6.05 mmol/L.
- Day 925 (ECOG 0): Hemoglobin 8.25 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 7.32 mmol/L.
- Day 991 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 6.3 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.23 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 6.27 mmol/L.
- Day 1,047 (ECOG 0): Immunoglobulin G 6.3 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.2 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.23 mmol/L.
- Day 1,195 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.77 mg/dL; Immunoglobulin G 7.73 g/L; Immunoglobulin A 1.7 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 150 ×10⁹/L.
- Day 1,261 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Immunoglobulin G 8.76 g/L; Immunoglobulin A 1.79 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.27 µg/mL; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day 1: Weight: 90 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Maternal Grandfather; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1602_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1602_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
